Gene-level copy-number profile of tumor specimen TCGA-BP-4964-01A from TCGA case TCGA-BP-4964, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.0 years (20,084 days).
Specimen TCGA-BP-4964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.1bff6750-00aa-404a-bb0a-c2e467c9b6bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BP-4964-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/52ead6d7-aade-4a16-a26e-f41909de7f76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,150; copy number 2: 58,122; copy number 3: 548.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BP-4964-01A-01D-1331-01): tumor purity 0.73, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
